TCGA case TCGA-K1-A6RU — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Fibromatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/306c53fb-640d-42ad-889a-abc5fd3ad778

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 66 years; Vital status: Dead; Days to death: 711 days (1.9 years).

Diagnoses (2)
1. Fibromyxosarcoma (the primary disease): ICD-O-3 morphology code: 8811/3; ICD-10 code: C49.2; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 66.7 years (24,356 days); Year of diagnosis: 2013; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis percent: 20; Necrosis present: Yes; Tumor depth descriptor: Deep.
2. Metastasis of diagnosis 1 (Fibromyxosarcoma), site: Bone, NOS. Age at diagnosis: 67.1 years (24,498 days); Days to diagnosis: 142 days; Prior treatment: Yes.

Follow-up (3 entries)
- Day 142 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 142 days.
- Days to follow up: 330 days; Disease response: With Tumor.
- Days to follow up: 711 days (1.9 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 26.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-K1-A6RU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 410 mg.
  Slide TCGA-K1-A6RU-01A-01-TSA: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-K1-A6RU-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Myxofibrosarcoma; Margin status: Positive; Tumor total necrosis: Moderate Necrosis (>=10, <50%).
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Thigh/knee.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.
- Drug treatment: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 143; Pharmaceutical therapy drug name: Adriamycin; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Radiation treatment: Radiation therapy ongoing indicator: No; Treatment best response: Radiographic Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 711 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 711 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 142 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-K1-A6RU-01A-11D-A32H-01): tumor purity 0.51, ploidy 3.54, whole-genome doublings 1.
